Surgical pathology report (de-identified scan), TCGA case TCGA-X6-A8C7, project TCGA-SARC (Sarcoma), tissue source site University of Iowa, specimen TCGA-X6-A8C7-01A (Primary Tumor).

---SURGICAL PATHOLOGY CONSULTATION--- (Accession

Status: Final result

Results

Collection Information

Specimen#	Collection Date	Collection Time	Collected By	Specimen Source	Specimen Description
-----------	-----------------	-----------------	--------------	-----------------	----------------------

Component Results

Component

DIAGNOSIS

Soft tissue and bone, left foot, resection:
Spindle cell sarcoma consistent with synovial sarcoma (1.6 cm).
Mitotic count: 15 per 10 HPF.
No significant tumor necrosis.
Margins negative.

Comment

Date reported: Pathologist (Electronic Signature)

Review

with previously biopsied L foot synovial sarcoma.

ISSUE SUBMITTED

A. L foot mass-stitch is proximal

GROSS

Received in saline, in a container labeled with the patient's name, hospital number and "L foot mass-stitch is proximal" is a 6.7 x 3.4 x 2.7 cm excision of skin with underlying yellow, lobular fibroadipose tissue and a suture at one tip designating the proximal margin. There is a 2.2 x 1.1 x 0.6 cm portion of sesamoid bone located at the deep/lateral aspect of the specimen, as indicated by . The surface of the skin is grey-tan, with a 5.8 cm in length x 0.1 cm in diameter linear defect, consistent with a previous incision located 0.3 cm from the proximal margin, 0.4 cm from the medial margin, 0.4 cm from the distal margin, and 0.5 cm from the lateral margin. The margins are inked as follows: Medial, orange; lateral, blue; deep, green. Sectioning reveals a 1.6 x 1.5 x 1.3 cm pink-tan to red-brown, variegated, firm, well-circumscribed lesion located 0.4 cm from lateral margin, 0.4 cm from the medial margin, 0.3 cm from the deep margin, 2.3 cm from the proximal margin, 4.3 cm from the distal margin, and 0.5 cm from the sesamoid bone. The skin defect extends to the lesion, surrounded by areas of hemorrhage and necrosis. The lesion grossly appears to have a thin, grey-tan capsule, <0.1 cm in average thickness. The remainder of the cut surfaces are yellow, lobular with focal areas of hemorrhage and necrosis underlying the skin defect. There are no additional lesions identified. Sections submitted: A1, proximal tip; A2, distal tip; A3-A5, lesion entirely submitted; A6, uninvolved proximal excision; A7, uninvolved distal excision to include sesamoid bone, following fixation and decalcification.

MICROSCOPIC

Microscopic examination performed and supports the diagnosis.
Performed by:

As the primary pathologist on this case, I have personally reviewed this case and edited the report as necessary.

Patient Release Status:

This result is not viewable by the patient.

Lab and Collection

---SURGICAL PATHOLOGY CONSULTATION---

Lab and Collection Information

Result History

---SURGICAL PATHOLOGY CONSULTATION---

Order Result History Report.

Result Entered On:

Lab Information

ICD O-3
Sarcoma, synovial biphasic
path 9043/3
Sarcoma, synovial spindle cell
9041/3
Site L foot NOS
C49.2
JW 11/24/13

Case Is (clerk):		

JW 10/31/13
11/20/13

Source: NCI Genomic Data Commons file 54e862fa-ae04-4cb1-8169-4e609923d7e7 (TCGA-X6-A8C7.2D46A7AD-6739-49E7-A39F-17C10087BC73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).